CCDI case PBCITU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/afaa4eb9-97d4-41c5-a710-65f246e471e2

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Spinal cord; Age at diagnosis: 13.9 years (5,068 days).

Biospecimens (3 samples)
- Sample 0DSYEB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DSYEH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DSYER: Tissue type: Tumor; Specimen type: Solid Tissue.
